Somatic mutation profile of tumor specimen TCGA-17-Z048-01A (aliquot TCGA-17-Z048-01A-01W-0746-08) from TCGA case TCGA-17-Z048, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z048-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c110f524-8d21-42ae-b391-78fd09e47a02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z048-11A (Solid Tissue Normal), aliquot TCGA-17-Z048-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d472f29e-ce7e-4ad4-a309-25f9a03d9199

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 15, Silent 9, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 2, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2310_2311insGGGTTA p.D770_N771insGL | In Frame Ins (INS) | VAF 102/256 reads (40%) | hotspot (GDC flag); catalogued as COSV51766421, COSV51769298, COSV51772603, COSV51772611, COSV51785587, COSV51800700, COSV51802530, COSV51822889, COSV51835502, COSV51850813, COSV51866095; called by mutect2, pindel, varscan2
- CCNQ | c.429+1G>T p.X143_splice | Splice Site (SNP) | VAF 36/141 reads (26%) | catalogued as COSV52343827, COSV52344210, COSV52346069; called by muse, mutect2, varscan2
- MSH4 | c.2487T>G p.Y829* | Nonsense Mutation (SNP) | VAF 35/150 reads (23%) | catalogued as rs757708300; called by muse, mutect2, varscan2
- MYBPHL | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs140919452; called by muse, mutect2, varscan2
- SETD4 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 62/356 reads (17%) | catalogued as rs540725974; called by muse, mutect2, varscan2
- SYT16 | c.1556C>T p.T519M | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777540095, COSV70856141; called by muse, mutect2, varscan2
- ZBTB21 | c.2195C>G p.S732C | Missense Mutation (SNP) | VAF 94/574 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1340971024, COSV60403133; called by muse, mutect2, varscan2
- AKAP6 | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRWD1 | c.2638T>G p.L880V | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CDK7 | c.872_874del p.K291del | In Frame Del (DEL) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- COQ9 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- CYB5R1 | c.185A>G p.K62R | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- DISP2 | c.2107C>G p.R703G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGFN1 | c.3010C>T p.L1004F (on ENST00000295591 / NM_001367841.1; = p.L3461F on NM_001164586.2) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- MBNL2 | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 75/310 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NEK1 | c.874A>G p.R292G | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NFXL1 | c.2555G>C p.R852T | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- OR5D13 | c.137G>C p.G46A | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- PCDHGC4 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- SIRPB1 | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 100/259 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.052); called by muse, mutect2
- SLC50A1 | c.583dup p.I195Nfs*33 | Frame Shift Ins (INS) | VAF 29/131 reads (22%) | called by mutect2, pindel, varscan2
- SWT1 | c.2057dup p.N686Kfs*3 | Frame Shift Ins (INS) | VAF 36/170 reads (21%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2838+1G>C p.X946_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- WDFY3 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.366); called by muse, varscan2
- ACSS1 | c.258C>G p.P86= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV60220915; called by muse, mutect2, varscan2
- CLPTM1L | c.1275T>C p.Y425= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- FAAH | c.675C>T p.I225= | Silent (SNP) | VAF 22/147 reads (15%) | catalogued as rs779485475, COSV54544082; called by muse, mutect2, varscan2
- FYB1 | c.243G>A p.P81= | Silent (SNP) | VAF 12/133 reads (9%) | catalogued as rs370543019; called by muse, mutect2
- GAD2 | c.1512C>A p.V504= | Silent (SNP) | VAF 57/482 reads (12%) | called by muse, mutect2, varscan2
- MYO1A | c.2364A>G p.L788= | Silent (SNP) | VAF 31/214 reads (14%) | called by muse, mutect2, varscan2
- NAE1 | c.855T>A p.I285= | Silent (SNP) | VAF 19/215 reads (9%) | called by muse, mutect2
- PRSS54 | c.954G>A p.R318= | Silent (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- TPM3 | c.294A>G p.E98= | Silent (SNP) | VAF 79/353 reads (22%) | catalogued as rs958436779, COSV55139576; called by muse, mutect2, varscan2
